Somatic mutation profile of tumor specimen C3L-07957-03 (aliquot CPT0533410006) from CPTAC case C3L-07957, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 65.3 years (23,840 days).
Specimen C3L-07957-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bca254b-0263-4948-8344-bc8d8042f12b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07957-31 (Blood Derived Normal), aliquot CPT0533540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d97c6cda-2cb7-4235-b2b1-04f66fe9c2b8

The open-access MAF lists 93 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 19, Intron 3, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 108/418 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 78/351 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMPRSS3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373058706, CM124935, CM124936; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOL2 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.133); catalogued as rs760928601, COSV50772910; called by muse, mutect2, varscan2
- ARFRP1 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs750436290, COSV53926356; called by muse, mutect2, varscan2
- ARHGEF12 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1051039253; called by muse, mutect2, varscan2
- BX255925.3 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT deleterious, low confidence (0.01); catalogued as rs995619805; called by muse, mutect2, varscan2
- CACNA2D3 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV55546323; called by muse, mutect2
- CCT8L2 | c.507G>C p.M169I | Missense Mutation (SNP) | VAF 55/531 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.059); catalogued as COSV63462828; called by muse, mutect2, varscan2
- COL1A1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 29/307 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs781774588; called by muse, mutect2, varscan2
- CRAMP1 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 68/646 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.08); catalogued as rs571857474, COSV51966113, COSV99246430; called by muse, mutect2, varscan2
- CUX2 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 58/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774991259, COSV55622878; called by muse, mutect2, varscan2
- DCAF12L1 | c.541T>A p.S181T | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780712210; called by muse, mutect2, varscan2
- DPYS | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 41/390 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs113309169; called by muse, mutect2, varscan2
- FNIP1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1411219564, COSV57196972; called by muse, mutect2, varscan2
- FOXL2 | c.1095C>A p.S365R | Missense Mutation (SNP) | VAF 64/469 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.068); catalogued as COSV100374726; called by muse, mutect2, varscan2
- GNA15 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 95/565 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1245473019; called by muse, mutect2, varscan2
- GPX6 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 44/509 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV100724757; called by muse, mutect2
- GRM1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs553512718, COSV51109088; called by muse, mutect2, varscan2
- KCNQ4 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 101/622 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1171470293; called by muse, mutect2, varscan2
- KIF19 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 55/472 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377150875, COSV100739040; called by muse, mutect2, varscan2
- KLHL29 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 165/687 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1014456936, COSV56022545; called by muse, mutect2, varscan2
- LAMC3 | c.4255C>T p.R1419W | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs147688904; called by muse, mutect2, varscan2
- MAP3K4 | c.4796C>T p.S1599L | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as COSV62330283; called by muse, mutect2, varscan2
- MYH9 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53381589; called by muse, mutect2, varscan2
- NEB | c.3235G>T p.A1079S | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV51420115; called by muse, mutect2, varscan2
- NFIX | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 74/635 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1193070672, COSV62179868; called by muse, mutect2, varscan2
- OR6K2 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs369203639, COSV100656859, COSV62743146; called by muse, mutect2, varscan2
- PCDH10 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 55/512 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.138); catalogued as rs1294176009; called by muse, mutect2, varscan2
- PCNX3 | c.4912G>A p.V1638I | Missense Mutation (SNP) | VAF 73/510 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs547456802; called by muse, mutect2, varscan2
- RANBP3 | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs776725293; called by muse, mutect2, varscan2
- RFX5 | c.116+1G>A p.X39_splice | Splice Site (SNP) | VAF 28/223 reads (13%) | catalogued as rs972632936, COSV51838069; called by muse, mutect2, varscan2
- RTL1 | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 72/625 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs561030751, COSV101128114; called by muse, mutect2, varscan2
- SCYL1 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 56/545 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1341531841; called by muse, mutect2
- SEMA5A | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 54/509 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs376772698; called by muse, mutect2, varscan2
- SEMA7A | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as rs774736648; called by muse, mutect2, varscan2
- SERGEF | c.164del p.T55Kfs*21 | Frame Shift Del (DEL) | VAF 43/402 reads (11%) | catalogued as rs749299415; called by mutect2, pindel, varscan2
- SPEF2 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 41/471 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV56796178, COSV99213995; called by muse, mutect2
- SS18L1 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 66/545 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.828); catalogued as rs759619267; called by muse, mutect2, varscan2
- TAF6 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1430659861; called by muse, mutect2, varscan2
- TATDN2 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55053006; called by muse, mutect2, varscan2
- TICAM1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 99/615 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376914657; called by muse, mutect2, varscan2
- TIE1 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 86/734 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs776717207; called by muse, mutect2, varscan2
- TNK1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 52/437 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs374420688; called by muse, mutect2, varscan2
- TNXB | c.9126G>T p.E3042D (on ENST00000647633; = p.E2795D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/690 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as rs1450052639; called by muse, varscan2
- TTN | c.7756dup p.I2586Nfs*3 (on ENST00000591111; = p.I2540Nfs*3 on NM_003319.4) | Frame Shift Ins (INS) | VAF 19/170 reads (11%) | catalogued as rs1553999983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ZFHX4 | c.3528G>T p.E1176D | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.116); catalogued as COSV50532002; called by muse, mutect2, varscan2
- BCOR | c.4815_4818del p.C1606Nfs*11 (on ENST00000378444 / NM_001123385.2; = p.C1572Nfs*11 on NM_017745.6) | Frame Shift Del (DEL) | VAF 53/252 reads (21%) | called by mutect2, pindel, varscan2
- C7orf61 | c.579C>G p.N193K | Missense Mutation (SNP) | VAF 34/994 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- CAND2 | c.2143G>T p.V715L (on ENST00000456430 / NM_001162499.2; = p.V622L on NM_012298.3) | Missense Mutation (SNP) | VAF 80/582 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASZ1 | c.4772A>G p.H1591R | Missense Mutation (SNP) | VAF 83/592 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CEP350 | c.7840G>A p.E2614K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.324); called by muse, mutect2
- CLNK | c.633C>T p.V211= | Splice Region (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- CNTNAP2 | c.1342T>A p.S448T | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2
- DEPP1 | c.311_319del p.P104_W107delinsR | In Frame Del (DEL) | VAF 59/558 reads (11%) | called by mutect2, pindel, varscan2
- DISC1 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF3B | c.595C>G p.R199G | Missense Mutation (SNP) | VAF 42/499 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2
- GALNT18 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 56/452 reads (12%) | called by muse, varscan2
- GAS2L1 | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 78/515 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- IGHA1 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 81/535 reads (15%) | called by muse, mutect2, varscan2
- KCNH5 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- KDM5B | c.4198C>G p.R1400G | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MAPK3 | c.283T>G p.F95V | Missense Mutation (SNP) | VAF 79/520 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MPRIP | c.2542C>G p.L848V | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NAA30 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 93/695 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH9 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- SEMA3E | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SP100 | c.1921A>G p.R641G | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TENM3 | c.6105T>G p.N2035K | Missense Mutation (SNP) | VAF 59/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRIM42 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 60/460 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ZFR2 | c.585C>A p.C195* | Nonsense Mutation (SNP) | VAF 65/441 reads (15%) | called by muse, mutect2, varscan2
- ACE | c.2802G>T p.L934= | Silent (SNP) | VAF 58/449 reads (13%) | called by muse, mutect2, varscan2
- CARMIL2 | c.2733G>A p.P911= | Silent (SNP) | VAF 81/556 reads (15%) | catalogued as rs762685250, COSV58023164; called by muse, mutect2, varscan2
- COBL | c.2529C>T p.H843= | Silent (SNP) | VAF 227/928 reads (24%) | catalogued as rs1417308359, COSV99473157; called by muse, mutect2, varscan2
- DCAF12L1 | c.540C>A p.P180= | Silent (SNP) | VAF 76/407 reads (19%) | catalogued as COSV64422501; called by muse, mutect2, varscan2
- DSCAML1 | c.5133G>A p.Q1711= (on ENST00000321322; = p.Q1651= on NM_020693.4) | Silent (SNP) | VAF 65/484 reads (13%) | called by muse, mutect2, varscan2
- GLI3 | c.2637G>A p.A879= | Silent (SNP) | VAF 157/656 reads (24%) | catalogued as COSV67895422; called by muse, mutect2, varscan2
- HOXD4 | c.102C>T p.A34= | Silent (SNP) | VAF 70/732 reads (10%) | called by muse, mutect2
- HSP90B1 | c.2076G>A p.P692= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as rs771669006, COSV55358077; called by muse, mutect2, varscan2
- MAGEA10 | c.1080C>T p.S360= | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as rs138141548; called by muse, mutect2, varscan2
- MKNK1 | c.1218C>T p.N406= | Silent (SNP) | VAF 47/623 reads (8%) | catalogued as rs752571512, COSV100361464; called by muse, mutect2
- MMP19 | c.453G>A p.A151= | Silent (SNP) | VAF 167/528 reads (32%) | catalogued as rs768729991; called by muse, mutect2, varscan2
- MTUS2 | c.2385C>T p.S795= | Silent (SNP) | VAF 53/403 reads (13%) | catalogued as rs749268070, COSV70915839, COSV70917454; called by muse, mutect2, varscan2
- MYF5 | c.462G>A p.S154= | Silent (SNP) | VAF 116/396 reads (29%) | catalogued as rs751777341, COSV57354383; called by muse, mutect2, varscan2
- MYH1 | c.5742T>C p.A1914= | Silent (SNP) | VAF 41/523 reads (8%) | called by muse, mutect2
- NOTCH4 | c.5382G>A p.E1794= | Silent (SNP) | VAF 99/694 reads (14%) | catalogued as COSV66682632; called by muse, varscan2
- SALL1 | c.1161G>A p.A387= | Silent (SNP) | VAF 56/519 reads (11%) | catalogued as rs200170000; called by muse, mutect2, varscan2
- SFTPB | c.846C>T p.S282= | Silent (SNP) | VAF 56/427 reads (13%) | catalogued as rs1234243117, COSV60893442; called by muse, mutect2, varscan2
- TRIM59 | c.1135C>T p.L379= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV59087015; called by muse, mutect2, varscan2
- TRPA1 | c.627T>A p.G209= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- KIAA1328 | c.1232+16620G>A | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- LBH | c.26+415C>T | Intron (SNP) | VAF 37/325 reads (11%) | called by muse, mutect2, varscan2
- RAVER1 | c.1431+358C>T | Intron (SNP) | VAF 79/576 reads (14%) | called by muse, mutect2, varscan2
